Somatic mutation profile of tumor specimen HTMCP-03-06-02376-01A (aliquot HTMCP-03-06-02376-01A-01D-10409) from CGCI case HTMCP-03-06-02376, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 72.1 years (26,323 days).
Specimen HTMCP-03-06-02376-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 27a54cfd-648b-430a-9b89-5fcaebb83dda.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HTMCP-03-06-02376-10A (Blood Derived Normal), aliquot HTMCP-03-06-02376-10A-01D-10409; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/08078cf1-24ef-4bbe-a46a-8581398b209d

The open-access MAF lists 26 somatic variants for this specimen: 20 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 5, Frame Shift Del 1, Frame Shift Ins 1, 3'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERBB2 | c.929C>T p.S310F | Missense Mutation (SNP) | VAF 3063/3117 reads (98%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1057519816, COSV54062198, COSV54062802; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADGRB1 | c.440G>A p.R147H | Missense Mutation (SNP) | VAF 14/21 reads (67%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.454); catalogued as rs974803416, COSV60099042; called by muse, mutect2, varscan2
- ASPM | c.9218G>A p.R3073K | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.867); catalogued as rs904280556; called by muse, mutect2, varscan2
- ELFN1 | c.2298del p.E767Sfs*16 | Frame Shift Del (DEL) | VAF 17/49 reads (35%) | catalogued as COSV70036940; called by mutect2, pindel, varscan2
- OLFM3 | c.38G>C p.S13T | Missense Mutation (SNP) | VAF 69/195 reads (35%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.038); catalogued as rs772160314; called by muse, mutect2, varscan2
- PHF20 | c.2701G>A p.G901S | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as rs746807394; called by muse, mutect2, varscan2
- PXDN | c.3998G>A p.R1333Q | Missense Mutation (SNP) | VAF 7/77 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.284); catalogued as rs935825802, COSV53233505; called by muse, mutect2
- SZT2 | c.1961G>A p.R654H | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs773445213; called by muse, mutect2, varscan2
- TTN | c.44444G>A p.R14815H (on ENST00000591111; = p.R7391H on NM_003319.4) | Missense Mutation (SNP) | VAF 37/113 reads (33%) | PolyPhen possibly damaging (0.46); catalogued as rs768914789, COSV59892620; ClinVar: benign / conflicting interpretations of pathogenicity / uncertain significance; called by muse, mutect2, varscan2
- CRAMP1 | c.3773G>A p.G1258D | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- ITGA8 | c.2761dup p.I921Nfs*44 | Frame Shift Ins (INS) | VAF 20/93 reads (22%) | called by mutect2, pindel, varscan2
- NIN | c.3638A>T p.D1213V | Missense Mutation (SNP) | VAF 24/183 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- PCDH15 | c.3182C>A p.A1061D | Missense Mutation (SNP) | VAF 9/127 reads (7%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.992); called by muse, mutect2
- PRUNE2 | c.7307A>G p.D2436G | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.528); called by muse, mutect2
- QRICH1 | c.2087A>G p.E696G | Missense Mutation (SNP) | VAF 12/192 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.007); called by muse, mutect2
- RAI1 | c.5566-1G>A p.X1856_splice | Splice Site (SNP) | VAF 10/50 reads (20%) | called by muse, mutect2, varscan2
- SYNE1 | c.4598G>T p.G1533V (on ENST00000367255 / NM_182961.4; = p.G1540V on NM_033071.3) | Missense Mutation (SNP) | VAF 18/326 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.031); called by muse, mutect2
- TACC2 | c.2425C>T p.P809S | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- VCAN | c.2940G>C p.K980N | Missense Mutation (SNP) | VAF 27/192 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- WRN | c.2413G>A p.D805N | Missense Mutation (SNP) | VAF 125/207 reads (60%) | SIFT tolerated (0.08); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- CPNE4 | c.30C>T p.S10= | Silent (SNP) | VAF 25/78 reads (32%) | catalogued as rs780788127, COSV101456589; called by muse, mutect2, varscan2
- FREM3 | c.2691C>T p.N897= | Silent (SNP) | VAF 75/167 reads (45%) | catalogued as rs376485134; called by muse, mutect2, varscan2
- PCDH15 | c.1845C>T p.R615= | Silent (SNP) | VAF 26/81 reads (32%) | called by muse, mutect2, varscan2
- PHF12 | c.1605G>A p.G535= | Silent (SNP) | VAF 28/103 reads (27%) | called by muse, mutect2, varscan2
- TBC1D25 | c.543A>G p.Q181= | Silent (SNP) | VAF 49/107 reads (46%) | catalogued as rs782425488; called by muse, mutect2, varscan2
- CCDC77 | c.*6A>G | 3'UTR (SNP) | VAF 42/73 reads (58%) | catalogued as rs755600704; called by muse, mutect2, varscan2
